Somatic mutation profile of tumor specimen TCGA-O1-A52J-01A (aliquot TCGA-O1-A52J-01A-11D-A25L-08) from TCGA case TCGA-O1-A52J, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 74.5 years (27,223 days).
Specimen TCGA-O1-A52J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 83a6a9b7-fb06-41a6-b299-2d75adaf8528.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-O1-A52J-10A (Blood Derived Normal), aliquot TCGA-O1-A52J-10A-01D-A25L-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9588875-a849-4a35-a90d-d96d402c3a88

The open-access MAF lists 196 somatic variants for this specimen: 146 protein-altering or splice-affecting, 46 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 125, Silent 46, Nonsense Mutation 9, Splice Site 4, Frame Shift Del 4, In Frame Del 2, Intron 2, Frame Shift Ins 1, Splice Region 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 27/72 reads (38%) | hotspot (GDC flag); catalogued as rs201744589, CM031387, COSV52661551, COSV52761493, COSV53353479, COSV53790595; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.2563A>T p.T855S | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV101330098; called by muse, mutect2, varscan2
- ABHD1 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.559); catalogued as COSV99574592; called by muse, mutect2, varscan2
- ABLIM3 | c.410T>C p.M137T | Missense Mutation (SNP) | VAF 54/111 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.063); catalogued as COSV100448551; called by muse, mutect2, varscan2
- ACAN | c.2649T>A p.S883R | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV100718434; called by muse, mutect2, varscan2
- ADAMTS14 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs374197954; called by muse, mutect2, varscan2
- ADAMTS16 | c.2097A>T p.K699N | Missense Mutation (SNP) | VAF 83/127 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.299); catalogued as COSV99941730; called by muse, mutect2, varscan2
- ADGRL3 | c.3101A>C p.Y1034S (on ENST00000506720 / NM_001322402.2; = p.Y966S on NM_015236.6) | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101547245; called by muse, mutect2, varscan2
- AFF2 | c.1176A>T p.E392D | Missense Mutation (SNP) | VAF 99/259 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99664758; called by muse, mutect2, varscan2
- AFMID | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100015017; called by muse, mutect2, varscan2
- AR | c.1112T>A p.L371Q | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV101018622; called by muse, mutect2, varscan2
- ARHGAP10 | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV100331374; called by muse, mutect2, varscan2
- ARHGEF9 | c.866G>T p.R289L | Missense Mutation (SNP) | VAF 70/204 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53645562, COSV99491993; called by muse, mutect2, varscan2
- ARHGEF9 | c.671G>T p.C224F | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99491997; called by muse, mutect2, varscan2
- BBX | c.968C>T p.S323F | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV57884906; called by muse, mutect2, varscan2
- BCHE | c.632C>G p.A211G | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs768341160, COSV100012739; called by muse, mutect2, varscan2
- BCO2 | c.1709A>T p.Y570F | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as COSV100730391; called by muse, mutect2, varscan2
- C6orf118 | c.254G>C p.R85P | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.071); catalogued as COSV100024685; called by muse, mutect2, varscan2
- CCKBR | c.941C>A p.P314Q | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.29); catalogued as COSV100582997, COSV58100822; called by muse, mutect2, varscan2
- CD28 | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100142438; called by muse, mutect2
- CDH13 | c.272G>A p.G91D | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.34); catalogued as rs866019796, COSV99227368; called by muse, mutect2, varscan2
- CFAP251 | c.1165G>T p.E389* | Nonsense Mutation (SNP) | VAF 32/94 reads (34%) | catalogued as COSV56613170, COSV99996224; called by muse, mutect2
- CILP | c.2384G>T p.R795L | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs564594161, COSV56024796, COSV99973582; called by muse, mutect2, varscan2
- COG2 | c.598A>G p.I200V | Missense Mutation (SNP) | VAF 79/159 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); catalogued as COSV100794712; called by muse, mutect2, varscan2
- COL4A5 | c.844G>C p.G282R | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as COSV100088226; called by muse, mutect2
- COL9A1 | c.584T>A p.F195Y | Missense Mutation (SNP) | VAF 68/225 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.042); catalogued as COSV100611623; called by muse, mutect2, varscan2
- CPB1 | c.667T>C p.Y223H | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99294379; called by muse, mutect2, varscan2
- CXorf38 | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 69/187 reads (37%) | catalogued as COSV100010441; called by muse, mutect2, varscan2
- DCC | c.2218T>A p.C740S | Missense Mutation (SNP) | VAF 63/131 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100501093; called by muse, mutect2, varscan2
- DGKB | c.28C>A p.L10I | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.15); PolyPhen benign (0.368); catalogued as COSV99340730; called by muse, mutect2, varscan2
- DIS3 | c.1405G>T p.D469Y | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100899931; called by muse, mutect2, varscan2
- DMD | c.10441C>A p.Q3481K | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.458); catalogued as CD115814, COSV100627990; called by muse, mutect2, varscan2
- DNAH9 | c.3675G>C p.Q1225H | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99306469; called by muse, mutect2, varscan2
- DOCK10 | c.5335G>T p.A1779S | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.42); catalogued as COSV99290142; called by muse, mutect2, varscan2
- DZIP1L | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as COSV100551465; called by muse, mutect2, varscan2
- ECEL1 | c.874G>T p.V292L | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.228); catalogued as CD132074, COSV100458810; called by muse, mutect2, varscan2
- EGFR | c.2239_2258delinsCA p.L747_P753delinsQ | In Frame Del (DEL) | VAF 20/83 reads (24%) | catalogued as rs121913437, COSV51785746; called by pindel, varscan2*
- EPG5 | c.2191G>T p.E731* | Nonsense Mutation (SNP) | VAF 16/40 reads (40%) | catalogued as COSV99957560; called by muse, mutect2, varscan2
- EPRS1 | c.3458G>T p.W1153L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100859413; called by muse, mutect2, varscan2
- F5 | c.444C>A p.Y148* | Nonsense Mutation (SNP) | VAF 26/276 reads (9%) | catalogued as COSV100889153; called by muse, mutect2
- FAR1 | c.492T>G p.D164E | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT tolerated (0.77); PolyPhen benign (0.006); catalogued as COSV100701597; called by muse, mutect2, varscan2
- FIGN | c.1072A>G p.N358D | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV100292538; called by muse, mutect2, varscan2
- GALNT13 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs1277554031, COSV101223407; called by muse, mutect2, varscan2
- GP1BA | c.615G>C p.K205N | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.09); catalogued as COSV99851058; called by muse, mutect2, varscan2
- HCCS | c.39G>T p.Q13H | Missense Mutation (SNP) | VAF 63/171 reads (37%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV100335760; called by muse, mutect2, varscan2
- HDC | c.874G>T p.G292W | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51068294, COSV99984138; called by muse, mutect2
- HECW1 | c.1820C>A p.A607D | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.299); catalogued as COSV101223891; called by muse, mutect2, varscan2
- HEPH | c.1996C>T p.Q666* (on ENST00000343002; = p.Q399* on NM_014799.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 19/88 reads (22%) | catalogued as COSV100295080; called by muse, mutect2, varscan2
- HTR7 | c.116C>A p.P39Q | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.011); catalogued as rs754591406, COSV53288785, COSV99519853; called by muse, mutect2
- HTRA1 | c.972+1G>A p.X324_splice | Splice Site (SNP) | VAF 16/45 reads (36%) | catalogued as rs1432594571, COSV100934766; called by muse, mutect2, varscan2
- IQSEC1 | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV99832030; called by muse, mutect2, varscan2
- KCTD17 | c.920G>A p.G307E (on ENST00000403888 / NM_001282684.1; = p.G283E on NM_024681.3) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV100695930; called by muse, mutect2, varscan2
- KDF1 | c.437G>T p.R146L | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.711); catalogued as COSV100264545; called by muse, mutect2, varscan2
- KRTAP21-1 | c.170G>T p.G57V | Missense Mutation (SNP) | VAF 165/252 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100624939; called by muse, mutect2, varscan2
- LAMA2 | c.299C>A p.T100K | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV101370596; called by muse, mutect2, varscan2
- LRATD1 | c.335C>A p.A112E | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs761312529, COSV99707183; called by muse, mutect2
- LRCH3 | c.1166A>C p.E389A | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV100605161; called by muse, mutect2, varscan2
- LRP1B | c.8362C>G p.P2788A | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.998); catalogued as COSV101254346, COSV101257939; called by muse, mutect2, varscan2
- LRP1B | c.4629G>C p.M1543I | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV101257940; called by muse, mutect2, varscan2
- MAGEA6 | c.750C>G p.F250L | Missense Mutation (SNP) | VAF 64/575 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs782585932, COSV61448617, COSV61449289; called by muse, mutect2, varscan2
- MAGEB6 | c.421G>T p.D141Y | Missense Mutation (SNP) | VAF 92/245 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.646); catalogued as COSV66873083; called by muse, mutect2, varscan2
- MAP3K19 | c.3787G>T p.G1263W | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100208778, COSV59639079; called by muse, mutect2, varscan2
- MMP25 | c.148G>T p.A50S | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.349); catalogued as rs1294987627, COSV100339506; called by muse, mutect2, varscan2
- MMUT | c.2124+1G>A p.X708_splice | Splice Site (SNP) | VAF 12/61 reads (20%) | catalogued as rs543029288, CS050817, COSV99222408; called by muse, mutect2, varscan2
- MROH9 | c.46C>A p.Q16K | Missense Mutation (SNP) | VAF 44/192 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as COSV100882820; called by muse, mutect2
- MRTFB | c.1943C>T p.S648F | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as COSV100371443; called by muse, mutect2, varscan2
- MTMR8 | c.1025G>T p.W342L | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100878468; called by muse, mutect2, varscan2
- MXRA5 | c.7828G>T p.D2610Y | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99477692; called by muse, mutect2, varscan2
- MYH9 | c.5227G>T p.G1743C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV99339188; called by muse, mutect2, varscan2
- NETO2 | c.715G>T p.V239F | Missense Mutation (SNP) | VAF 79/176 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100292502; called by muse, mutect2, varscan2
- NGF | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV65688547; called by muse, mutect2, varscan2
- NOD2 | c.540+1G>T p.X180_splice | Splice Site (SNP) | VAF 25/80 reads (31%) | catalogued as COSV100318669; called by muse, mutect2, varscan2
- NRDC | c.1305A>T p.R435S | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV100703521; called by muse, mutect2, varscan2
- NUMA1 | c.3893G>T p.R1298L | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV61186107; called by muse, mutect2, varscan2
- OGT | c.1895G>T p.G632V | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101035489; called by muse, mutect2, varscan2
- OR10K2 | c.852G>T p.L284F | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100149547, COSV59222605; called by muse, mutect2, varscan2
- OR2M4 | c.730C>A p.H244N | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.4); catalogued as COSV100141240, COSV60708312; called by muse, mutect2, varscan2
- OR2M5 | c.611T>C p.I204T | Missense Mutation (SNP) | VAF 219/531 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV63546179; called by muse, mutect2, varscan2
- OR4A15 | c.461C>A p.S154* | Nonsense Mutation (SNP) | VAF 76/269 reads (28%) | catalogued as COSV100124198; called by muse, mutect2, varscan2
- OR5A1 | c.344G>T p.C115F | Missense Mutation (SNP) | VAF 96/285 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100118403; called by muse, mutect2, varscan2
- OR6K2 | c.62G>T p.W21L | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.028); catalogued as COSV62743191; called by muse, mutect2, varscan2
- ORC1 | c.1937G>T p.R646L | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV100856696; called by muse, mutect2, varscan2
- PANK4 | c.161T>G p.V54G | Missense Mutation (SNP) | VAF 63/165 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.96); catalogued as COSV101022481; called by muse, mutect2, varscan2
- PCDHB10 | c.2021C>A p.P674Q | Missense Mutation (SNP) | VAF 124/175 reads (71%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99504537; called by muse, mutect2, varscan2
- PCDHB14 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as rs1396470404, COSV99506040; called by mutect2, varscan2
- PCDHB2 | c.807G>T p.R269S | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV99522925, COSV99523305; called by muse, mutect2, varscan2
- PCDHB7 | c.2299C>A p.P767T | Missense Mutation (SNP) | VAF 47/307 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as COSV50767901, COSV99177100; called by muse, mutect2, varscan2
- PCDHB7 | c.2300C>A p.P767Q | Missense Mutation (SNP) | VAF 47/307 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV99177102; called by muse, mutect2, varscan2
- PCDHGA2 | c.649G>T p.G217W | Missense Mutation (SNP) | VAF 52/100 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV54036069; called by muse, mutect2, varscan2
- PCDHGA2 | c.650G>T p.G217V | Missense Mutation (SNP) | VAF 51/100 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99541152; called by muse, mutect2, varscan2
- PCLO | c.13136G>T p.G4379V | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61621853; called by muse, mutect2, varscan2
- PDE1B | c.436G>C p.V146L | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.15); catalogued as COSV99672653; called by muse, mutect2, varscan2
- PDK3 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 131/443 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100998177; called by muse, mutect2, varscan2
- PIWIL1 | c.847A>T p.M283L | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.18); catalogued as rs1335495468, COSV99806603; called by muse, mutect2, varscan2
- PPP3R2 | c.195C>A p.D65E | Missense Mutation (SNP) | VAF 51/92 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.369); catalogued as COSV100701600; called by muse, mutect2, varscan2
- RBM47 | c.1454A>G p.D485G (on ENST00000295971 / NM_001098634.2; = p.D416G on NM_019027.4) | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as rs751114219, COSV99921007; called by muse, mutect2, varscan2
- RFX6 | c.1437+1G>T p.X479_splice | Splice Site (SNP) | VAF 34/85 reads (40%) | catalogued as COSV100263885; called by muse, mutect2, varscan2
- RMND5A | c.973G>T p.G325C | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99373801; called by muse, mutect2, varscan2
- SDK1 | c.1804C>T p.R602W | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1405073262, COSV67373590; called by muse, mutect2, varscan2
- SDK1 | c.5689G>T p.G1897W | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101269536; called by muse, mutect2, varscan2
- SH3GL3 | c.642G>T p.Q214H | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.434); catalogued as rs766510412, COSV100196969; called by muse, mutect2, varscan2
- SLC18A1 | c.796C>A p.L266M | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99368687; called by muse, mutect2, varscan2
- SLC24A2 | c.538A>G p.M180V | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99646883; called by muse, mutect2, varscan2
- SLC2A9 | c.465G>T p.M155I | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV99304877; called by muse, mutect2, varscan2
- SLC30A10 | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV100751535; called by muse, mutect2
- SLC38A2 | c.146A>T p.Q49L | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.112); catalogued as COSV99873973; called by muse, mutect2, varscan2
- SLITRK3 | c.1789C>A p.L597I | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as COSV99579511; called by muse, mutect2, varscan2
- SMO | c.571G>C p.G191R | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99976800; called by mutect2, varscan2
- SMPD3 | c.1814G>A p.R605H | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54711543; called by muse, mutect2
- SNTG2 | c.1228G>T p.A410S | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.194); catalogued as COSV100423316; called by muse, mutect2, varscan2
- SORCS1 | c.726G>T p.K242N | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.848); catalogued as COSV53881730; called by muse, mutect2, varscan2
- SPRYD7 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100709850; called by muse, mutect2, varscan2
- SSTR1 | c.1045G>T p.E349* | Nonsense Mutation (SNP) | VAF 65/137 reads (47%) | catalogued as COSV99942952; called by muse, mutect2, varscan2
- SYNE1 | c.11583A>T p.S3861= (on ENST00000367255 / NM_182961.4; = p.S3846= on NM_033071.3) | Splice Region (SNP) | VAF 74/246 reads (30%) | catalogued as COSV99569214; called by muse, mutect2, varscan2
- SYNPO2 | c.2015A>T p.E672V | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100205849; called by muse, mutect2, varscan2
- TAF4B | c.363T>A p.S121R | Missense Mutation (SNP) | VAF 8/214 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99300465; called by muse, mutect2
- TENM2 | c.1363C>T p.R455W (on ENST00000518659 / NM_001122679.2; = p.R223W on NM_001080428.3) | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs752898554, COSV69143752; called by muse, mutect2, varscan2
- THBD | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as COSV101001896; called by muse, mutect2
- TLK2 | c.1452G>C p.E484D (on ENST00000326270 / NM_001284333.2; = p.E462D on NM_006852.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); catalogued as COSV58301118; called by muse, mutect2, varscan2
- TLL1 | c.1603C>T p.R535C | Missense Mutation (SNP) | VAF 55/111 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as rs746485015, COSV99287784; called by muse, mutect2, varscan2
- TP63 | c.610C>A p.Q204K | Missense Mutation (SNP) | VAF 82/259 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); catalogued as COSV99287432; called by muse, mutect2, varscan2
- TRAIP | c.879A>C p.L293F | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV100513285; called by muse, mutect2, varscan2
- TRIM25 | c.353C>A p.T118K | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100381018; called by muse, mutect2, varscan2
- TRIM51 | c.1324C>A p.P442T | Missense Mutation (SNP) | VAF 74/316 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99792489; called by muse, mutect2, varscan2
- TRIML2 | c.964C>G p.H322D | Missense Mutation (SNP) | VAF 49/255 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100456164; called by muse, mutect2, varscan2
- TRPA1 | c.991G>T p.V331L | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.028); catalogued as COSV100084494, COSV51554931; called by muse, mutect2, varscan2
- TXNDC2 | c.678G>C p.K226N (on ENST00000306084 / NM_001098529.2; = p.K159N on NM_032243.6) | Missense Mutation (SNP) | VAF 61/139 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.096); catalogued as COSV100046298, COSV60153168; called by muse, mutect2, varscan2
- UGT2A3 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99279961; called by muse, mutect2, varscan2
- URGCP | c.1319G>T p.R440L (on ENST00000453200 / NM_001077663.3; = p.R431L on NM_017920.4) | Missense Mutation (SNP) | VAF 67/214 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.493); catalogued as COSV99787501; called by muse, mutect2, varscan2
- WRAP53 | c.721G>C p.D241H | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.894); catalogued as rs1327608159, COSV99872780; called by muse, mutect2, varscan2
- WWC3 | c.393G>T p.M131I | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV101081550; called by muse, mutect2, varscan2
- ZFHX4 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); catalogued as rs760459528, COSV99264304; called by muse, mutect2, varscan2
- ZIC4 | c.281C>G p.A94G | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.079); catalogued as COSV101268028, COSV67172402; called by muse, mutect2, varscan2
- ZNF329 | c.1377G>C p.Q459H | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as COSV100798768; called by muse, mutect2, varscan2
- ZNF512B | c.1325G>A p.G442E | Missense Mutation (SNP) | VAF 136/529 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99412253; called by muse, mutect2, varscan2
- ZNF75D | c.637G>T p.E213* | Nonsense Mutation (SNP) | VAF 27/87 reads (31%) | catalogued as COSV100883663; called by muse, mutect2, varscan2
- FGD6 | c.2157del p.E720Sfs*74 | Frame Shift Del (DEL) | VAF 56/119 reads (47%) | called by mutect2, pindel, varscan2
- FOXD4L3 | c.1108del p.L370Ffs*58 | Frame Shift Del (DEL) | VAF 17/83 reads (20%) | called by mutect2, pindel, varscan2
- IGHE | c.531G>C p.E177D | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); called by muse, mutect2
- IGKV2D-24 | c.124T>A p.S42T | Missense Mutation (SNP) | VAF 82/208 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KIR2DS4 | c.325del p.Y109Ifs*13 | Frame Shift Del (DEL) | VAF 224/513 reads (44%) | called by mutect2, pindel, varscan2
- NUP210 | c.4990G>A p.A1664T | Missense Mutation (SNP) | VAF 10/292 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- RFC1 | c.436_453del p.E146_K151del | In Frame Del (DEL) | VAF 20/44 reads (45%) | called by mutect2, pindel
- VCAN | c.5023dup p.R1675Kfs*9 | Frame Shift Ins (INS) | VAF 84/203 reads (41%) | called by mutect2, pindel, varscan2
- YY2 | c.702G>C p.Q234H | Missense Mutation (SNP) | VAF 82/614 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by mutect2, varscan2
- YY2 | c.706del p.A236Qfs*6 | Frame Shift Del (DEL) | VAF 72/627 reads (11%) | called by mutect2, pindel, varscan2
- ADGRG4 | c.5433C>A p.A1811= | Silent (SNP) | VAF 133/399 reads (33%) | catalogued as COSV99795900; called by muse, mutect2
- ASXL3 | c.4047T>C p.N1349= | Silent (SNP) | VAF 109/325 reads (34%) | catalogued as COSV99325442; called by muse, mutect2, varscan2
- ATP8B4 | c.396G>T p.V132= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99466191; called by muse, mutect2, varscan2
- ATRNL1 | c.2544A>G p.A848= | Silent (SNP) | VAF 34/90 reads (38%) | catalogued as rs375737159; called by muse, mutect2, varscan2
- BACE2 | c.1377C>T p.P459= | Silent (SNP) | VAF 12/105 reads (11%) | catalogued as rs773478396; called by muse, mutect2, varscan2
- BPIFB6 | c.819C>A p.S273= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as COSV100848532; called by muse, mutect2, varscan2
- BPTF | c.2274G>T p.G758= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as rs576607155, COSV100075213; called by muse, mutect2, varscan2
- CACNB2 | c.1236G>T p.G412= (on ENST00000324631 / NM_201596.3; = p.G357= on NM_000724.4) | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV99995181; called by muse, mutect2, varscan2
- CAMSAP1 | c.2286C>T p.S762= | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as rs937598329, COSV100410033; called by muse, mutect2, varscan2
- CCR3 | c.24T>A p.V8= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV100656595; called by muse, mutect2, varscan2
- CMYA5 | c.6201T>C p.S2067= | Silent (SNP) | VAF 106/164 reads (65%) | catalogued as COSV101484155; called by muse, mutect2, varscan2
- EFNB1 | c.567C>A p.V189= | Silent (SNP) | VAF 32/108 reads (30%) | catalogued as COSV99214899; called by muse, mutect2, varscan2
- EPHA5 | c.2755C>A p.R919= | Silent (SNP) | VAF 36/107 reads (34%) | catalogued as COSV56666563; called by muse, mutect2, varscan2
- F9 | c.51C>A p.I17= | Silent (SNP) | VAF 114/273 reads (42%) | catalogued as COSV99496659; called by muse, mutect2, varscan2
- FOXF1 | c.258G>T p.R86= | Silent (SNP) | VAF 92/175 reads (53%) | catalogued as COSV99296575; called by muse, mutect2, varscan2
- GABRA3 | c.447G>A p.P149= | Silent (SNP) | VAF 48/381 reads (13%) | catalogued as rs771451170, COSV100942974; called by muse, mutect2, varscan2
- GLI3 | c.1254G>A p.T418= | Silent (SNP) | VAF 32/126 reads (25%) | catalogued as rs766473517, COSV101229927; called by muse, mutect2, varscan2
- IMPG2 | c.1740A>G p.L580= | Silent (SNP) | VAF 75/199 reads (38%) | catalogued as COSV99515818; called by muse, mutect2, varscan2
- MAGEC3 | c.1188C>A p.P396= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV100025641; called by muse, mutect2, varscan2
- MAPK14 | c.948T>C p.D316= | Silent (SNP) | VAF 77/157 reads (49%) | catalogued as COSV100005009; called by muse, mutect2, varscan2
- MRTFB | c.1944C>T p.S648= | Silent (SNP) | VAF 45/110 reads (41%) | catalogued as rs1377892976, COSV100371446; called by muse, mutect2, varscan2
- MYO16 | c.1905T>G p.R635= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as COSV99194087; called by muse, mutect2, varscan2
- MYPN | c.3522C>T p.I1174= | Silent (SNP) | VAF 24/117 reads (21%) | catalogued as rs1160604856, COSV100590178; called by muse, mutect2, varscan2
- NLN | c.1779G>T p.S593= | Silent (SNP) | VAF 20/161 reads (12%) | catalogued as rs750131777, COSV101114362; called by muse, mutect2, varscan2
- NME8 | c.1449G>T p.V483= | Silent (SNP) | VAF 23/94 reads (24%) | catalogued as COSV99553481; called by muse, mutect2, varscan2
- NOS1 | c.4029C>A p.A1343= | Silent (SNP) | VAF 75/264 reads (28%) | catalogued as COSV100500073; called by muse, mutect2, varscan2
- OR2T10 | c.732C>T p.H244= | Silent (SNP) | VAF 26/114 reads (23%) | catalogued as COSV100393745, COSV57897393; called by muse, mutect2, varscan2
- PGPEP1L | c.171C>G p.T57= | Silent (SNP) | VAF 49/133 reads (37%) | catalogued as COSV100967346, COSV66708954; called by muse, mutect2, varscan2
- PLXNB2 | c.858G>A p.A286= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs538789586, COSV100834131; called by muse, mutect2, varscan2
- PTCHD3 | c.63G>T p.P21= | Silent (SNP) | VAF 16/136 reads (12%) | catalogued as COSV71257312; called by muse, mutect2, varscan2
- PTPRT | c.870G>T p.T290= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV100628394; called by muse, mutect2, varscan2
- REM2 | c.378C>A p.G126= | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as COSV99944708; called by muse, mutect2, varscan2
- RYR2 | c.10920G>A p.L3640= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV100771314; called by muse, mutect2, varscan2
- SDCCAG8 | c.1806A>G p.E602= | Silent (SNP) | VAF 68/143 reads (48%) | catalogued as COSV100654369; called by muse, mutect2, varscan2
- SGCZ | c.165G>T p.L55= | Silent (SNP) | VAF 47/125 reads (38%) | catalogued as COSV101170449; called by muse, mutect2, varscan2
- SIM1 | c.933G>A p.A311= | Silent (SNP) | VAF 7/88 reads (8%) | catalogued as COSV99492485; called by muse, mutect2
- SLC12A5 | c.3234G>T p.R1078= (on ENST00000454036 / NM_001134771.2; = p.R1055= on NM_020708.5) | Silent (SNP) | VAF 44/152 reads (29%) | catalogued as COSV99275739; called by muse, mutect2, varscan2
- SLX4 | c.3571C>T p.L1191= | Silent (SNP) | VAF 31/313 reads (10%) | catalogued as COSV99568225; called by muse, mutect2, varscan2
- SP4 | c.1047C>T p.S349= | Silent (SNP) | VAF 34/106 reads (32%) | catalogued as rs896852699, COSV99754658; called by muse, mutect2, varscan2
- SPN | c.672T>C p.S224= | Silent (SNP) | VAF 74/184 reads (40%) | catalogued as rs1320594586, COSV100788833; called by muse, mutect2, varscan2
- STMN2 | c.222A>G p.P74= | Silent (SNP) | VAF 34/59 reads (58%) | catalogued as COSV99626583; called by muse, mutect2, varscan2
- STRIP2 | c.897C>T p.G299= | Silent (SNP) | VAF 19/132 reads (14%) | catalogued as COSV99973897; called by muse, mutect2, varscan2
- TJP1 | c.1434C>T p.I478= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as rs367703610; called by muse, mutect2, varscan2
- TPH2 | c.822G>T p.T274= | Silent (SNP) | VAF 67/126 reads (53%) | catalogued as COSV100422148; called by muse, mutect2, varscan2
- VPS54 | c.2469G>T p.V823= | Silent (SNP) | VAF 39/110 reads (35%) | catalogued as COSV99708306; called by muse, mutect2, varscan2
- ZIK1 | c.558G>T p.L186= | Silent (SNP) | VAF 46/93 reads (49%) | catalogued as COSV56738512; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503665 del AT | 5'Flank (DEL) | VAF 25/102 reads (25%) | called by mutect2, pindel, varscan2
- MIR19B1 | n.2A>C | RNA (SNP) | VAF 83/186 reads (45%) | called by muse, mutect2, varscan2
- RPGR | c.2520+210G>T | Intron (SNP) | VAF 29/86 reads (34%) | catalogued as rs1229557261, COSV100140136; called by muse, mutect2, varscan2
- SV2C | c.581-20892G>C | Intron (SNP) | VAF 27/302 reads (9%) | called by muse, mutect2
